Gene-level copy-number profile of tumor specimen TCGA-24-2262-01A from TCGA case TCGA-24-2262, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.1 years (20,861 days).
Specimen TCGA-24-2262-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.9c67fe94-0cb2-4fc5-8349-5fb77875ce28.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2262-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9510eb8f-4f20-4a87-9141-337f425a3b2b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 12,456; copy number 2: 37,739; copy number 3: 6,828; copy number 4: 2,310; copy number 5: 438; copy number 6: 11; copy number 12: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2262-01A-01D-0704-01): tumor purity 0.7, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:15,066,207–15,068,651, 1 gene: AC006458.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 481 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,754,301–152,196,699, 143 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:234,261,706–235,344,532, 41 genes, copy number 5: AL122008.1, SLC35F3-AS1, AL122008.2, MIR4671, AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753, RPL23AP23, GGPS1.
- chr1:235,336,806–235,367,366, 3 genes, copy number 5: AL391994.1, AL357556.1, AL357556.5.
- chr2:27,771,717–27,988,087, 1 gene, copy number 5 (within-gene range 3–5): MRPL33.
- chr2:27,889,941–29,052,230, 28 genes, copy number 5 (within-gene range 4–5): BABAM2, MYG1P1, MIR4263, FAM133EP, AC096552.1, AC093690.1, RPL23AP34, FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1, PLB1, SNRPGP7, AC074011.1, RNA5SP89, AC092164.1, PPP1CB, SPDYA, AC097724.1, TRMT61B, WDR43, SNORD92, SNORD53, Y_RNA, SNORD53B, TOGARAM2, Y_RNA.
- chr3:139,003,962–139,859,894, 25 genes, copy number 5: PRR23A, MRPS22, PRR23B, PRR23C, RPL7L1P7, BPESC1, PISRT1, AC119740.1, AC024933.2, AC024933.1, COPB2, U6, AC046134.2, RBP2, AC097103.1, ACTG1P1, RBP1, NMNAT3, AC046134.1, RN7SKP124, RN7SL724P, AC110716.2, AC110716.1, AC016933.1, TRMT112P5.
- chr7:51,471,717–53,947,804, 24 genes, copy number 5: AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854.
- chr7:54,201,224–54,202,421, 1 gene, copy number 5: AC092848.1.
- chr7:98,252,379–98,479,225, 6 genes, copy number 5 (within-gene range 3–5): BRI3, BAIAP2L1, AC093799.1, RPS3AP26, PPIAP82, AC074121.1.
- chr7:107,808,734–108,995,029, 17 genes, copy number 5: PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1.
- chr8:125,348,196–126,008,930, 5 genes, copy number 6: AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1.
- chr8:125,900,951–126,001,001, 3 genes, copy number 6: RNU6-442P, SOD1P3, AC024681.2.
- chr11:65,066,300–66,244,744, 91 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:77,066,961–78,215,232, 34 genes, copy number 6–12 (within-gene range 3–12): CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35.
- chr11:78,223,815–78,225,909, 1 gene, copy number 12: AP002985.1.
- chr11:120,619,934–120,620,267, 1 gene, copy number 5: ELOCP22.
- chr20:63,488,013–64,313,132, 57 genes, copy number 5: EEF1A2, AL121829.1, PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 10,915. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
